Somatic mutation profile of cancer-model specimen HCM-CSHL-0374-C25-85A (3D Organoid, passage 17; aliquot HCM-CSHL-0374-C25-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0374-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Intraductal papillary-mucinous carcinoma, invasive; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 74.7 years (27,272 days).
Specimen HCM-CSHL-0374-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 17.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d9c994a-a07f-4eb1-8f1a-09ed468d4e0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0374-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0374-C25-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a35431f-2378-4773-98eb-309d3fda62ef

The open-access MAF lists 99 somatic variants for this specimen: 72 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 23, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 196/293 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOB | c.10690G>A p.E3564K | Missense Mutation (SNP) | VAF 101/444 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99263375; called by muse, mutect2, varscan2
- ARID3B | c.1585G>A p.G529S (on ENST00000622429 / NM_001307939.1; = p.G528S on NM_006465.4) | Missense Mutation (SNP) | VAF 102/518 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs529652330; called by muse, varscan2
- ARL15 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs765097364; called by muse, mutect2, varscan2
- BPIFC | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775661829, COSV55916396; called by muse, mutect2, varscan2
- BRINP1 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56300938; called by muse, mutect2, varscan2
- CDK14 | c.1154A>C p.K385T (on ENST00000380050 / NM_001287135.2; = p.K367T on NM_012395.3) | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56029741; called by muse, mutect2
- DMRT3 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 186/444 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777294931; called by muse, mutect2, varscan2
- DNAH8 | c.5492C>T p.T1831M | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760382625; called by muse, mutect2, varscan2
- DSC2 | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM166751; called by muse, mutect2, varscan2
- ENPEP | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 183/357 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs915463280, COSV54453232; called by muse, mutect2, varscan2
- FNDC7 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 289/411 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs572970288, COSV54752204; called by muse, mutect2, varscan2
- GATA1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782632688, COSV64962877; called by muse, mutect2, varscan2
- HIVEP3 | c.4642C>T p.P1548S | Missense Mutation (SNP) | VAF 235/388 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1358942201; called by muse, mutect2, varscan2
- IFNL1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 93/881 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs749411125; called by muse, mutect2, varscan2
- ITPR3 | c.7808C>T p.P2603L | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750669412; called by muse, mutect2, varscan2
- KIAA1958 | c.1441A>G p.I481V | Missense Mutation (SNP) | VAF 132/383 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs749207961; called by muse, mutect2, varscan2
- NEGR1 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60852524; called by muse, mutect2, varscan2
- NUP210 | c.4527C>G p.S1509R | Missense Mutation (SNP) | VAF 199/200 reads (100%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV54405068; called by muse, mutect2, varscan2
- PCDH10 | c.1411T>A p.Y471N | Missense Mutation (SNP) | VAF 22/607 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52104471; called by muse, mutect2
- PCDH8 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434424918; called by muse, mutect2
- PCDHGA6 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 413/879 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); catalogued as COSV53933953; called by muse, mutect2, varscan2
- PKHD1 | c.2090C>T p.T697M | Missense Mutation (SNP) | VAF 86/574 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs377415956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG3 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 534/1081 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs369614691; called by muse, mutect2, varscan2
- PTPRN | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 106/497 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs764566877, COSV55350334; called by muse, mutect2, varscan2
- RASA3 | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 249/274 reads (91%) | SIFT tolerated (0.49); PolyPhen benign (0.31); catalogued as rs1161979578, COSV61867228; called by muse, mutect2, varscan2
- RBM19 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.59); catalogued as rs373528615; called by muse, mutect2, varscan2
- RUNX1T1 | c.1723G>A p.G575R (on ENST00000265814 / NM_001198628.1; = p.G548R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/550 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs760717058; called by muse, mutect2, varscan2
- SATB2 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 201/401 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53494135; called by muse, mutect2, varscan2
- SMARCAL1 | c.1594C>T p.L532F | Missense Mutation (SNP) | VAF 193/383 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs968239393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOX6 | c.1511G>A p.R504Q (on ENST00000528429 / NM_001145819.2; = p.R477Q on NM_017508.3) | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs1004109180, COSV57047333; called by muse, mutect2, varscan2
- ST8SIA4 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 136/311 reads (44%) | PolyPhen benign (0.076); catalogued as rs1394330320, COSV51513558; called by muse, mutect2, varscan2
- SZT2 | c.8428C>T p.R2810C (on ENST00000634258 / NM_001365999.1; = p.R2753C on NM_015284.4) | Missense Mutation (SNP) | VAF 107/319 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs769123289; called by muse, mutect2, varscan2
- TCF15 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 296/537 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1233735209; called by muse, mutect2, varscan2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 122/172 reads (71%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- TP53BP2 | c.1474C>T p.R492W (on ENST00000343537 / NM_001031685.3; = p.R363W on NM_005426.2) | Missense Mutation (SNP) | VAF 61/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs61758079; called by muse, mutect2, varscan2
- UBE2E3 | c.473C>G p.T158S | Missense Mutation (SNP) | VAF 158/358 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1558940397; called by muse, mutect2, varscan2
- ZIM2 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 114/489 reads (23%) | catalogued as COSV55638558; called by muse, mutect2, varscan2
- ZNF609 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 256/517 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182000412; called by muse, mutect2, varscan2
- ADGRV1 | c.6211T>G p.S2071A | Missense Mutation (SNP) | VAF 186/336 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ADH1C | c.157_158insAG p.V53Efs*8 | Frame Shift Ins (INS) | VAF 175/461 reads (38%) | called by mutect2, pindel, varscan2
- B3GNT3 | c.691dup p.R231Pfs*32 | Frame Shift Ins (INS) | VAF 95/232 reads (41%) | called by mutect2, pindel, varscan2
- BAZ2B | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC181 | c.182A>C p.H61P | Missense Mutation (SNP) | VAF 68/440 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- COL4A6 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 113/224 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CTNND1 | c.1778A>T p.E593V | Missense Mutation (SNP) | VAF 203/331 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLG1 | c.2329A>C p.K777Q (on ENST00000419354 / NM_001290983.1; = p.K799Q on NM_004087.2) | Missense Mutation (SNP) | VAF 82/463 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DMXL2 | c.6649dup p.T2217Nfs*5 | Frame Shift Ins (INS) | VAF 199/492 reads (40%) | called by mutect2, pindel, varscan2
- GIMAP1 | c.198C>A p.C66* | Nonsense Mutation (SNP) | VAF 142/455 reads (31%) | called by muse, mutect2, varscan2
- HCN4 | c.1350G>T p.W450C | Missense Mutation (SNP) | VAF 151/305 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK17 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 726/972 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L3MBTL2 | c.763A>T p.S255C | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- MYO3A | c.4459C>A p.P1487T | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52R1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 114/357 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- OR5L1 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 264/413 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- OR5W2 | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHGA10 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 412/830 reads (50%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGR | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 144/741 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PHYHIPL | c.559T>A p.Y187N | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHYKPL | c.362T>A p.L121Q | Missense Mutation (SNP) | VAF 199/413 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- QSOX1 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 151/755 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- RSU1 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SMARCAD1 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TICRR | c.740del p.S247Ffs*18 | Frame Shift Del (DEL) | VAF 295/620 reads (48%) | called by mutect2, pindel, varscan2
- TMEM115 | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- TMEM204 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 163/364 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TTC34 | c.926T>C p.F309S | Missense Mutation (SNP) | VAF 219/643 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13C | c.59_84del p.E20Afs*12 | Frame Shift Del (DEL) | VAF 90/867 reads (10%) | called by mutect2, pindel
- WDFY4 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 83/402 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZC3H12B | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 156/261 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFP62 | c.1444T>C p.C482R (on ENST00000502412 / NM_001377944.1; = p.C449R on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 175/404 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF578 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ABR | c.159G>A p.S53= | Silent (SNP) | VAF 401/401 reads (100%) | catalogued as rs147154003; called by muse, mutect2, varscan2
- ADCY5 | c.1776C>T p.A592= | Silent (SNP) | VAF 120/577 reads (21%) | catalogued as rs1331114104; called by muse, mutect2, varscan2
- CDH18 | c.438C>T p.I146= | Silent (SNP) | VAF 96/384 reads (25%) | called by muse, varscan2
- CHD5 | c.2091C>T p.G697= | Silent (SNP) | VAF 265/413 reads (64%) | catalogued as rs148297777; called by muse, mutect2, varscan2
- CLN8 | c.432T>G p.L144= | Silent (SNP) | VAF 272/554 reads (49%) | called by mutect2, varscan2
- EFR3B | c.267C>T p.C89= | Silent (SNP) | VAF 184/413 reads (45%) | called by muse, varscan2
- FASN | c.4146C>T p.S1382= | Silent (SNP) | VAF 116/749 reads (15%) | called by muse, mutect2, varscan2
- GLI2 | c.927C>T p.A309= | Silent (SNP) | VAF 30/810 reads (4%) | called by muse, mutect2
- KSR2 | c.819G>A p.P273= | Silent (SNP) | VAF 171/530 reads (32%) | catalogued as rs372317080; called by muse, mutect2, varscan2
- MAS1L | c.936C>T p.I312= | Silent (SNP) | VAF 22/382 reads (6%) | catalogued as COSV65808885; called by muse, mutect2
- OPLAH | c.1785G>A p.Q595= | Silent (SNP) | VAF 164/728 reads (23%) | called by muse, mutect2, varscan2
- OR2C3 | c.759C>T p.Y253= | Silent (SNP) | VAF 190/487 reads (39%) | catalogued as rs529863004, COSV63574816; called by muse, mutect2, varscan2
- POTEE | c.1950G>A p.T650= | Silent (SNP) | VAF 71/353 reads (20%) | catalogued as rs753024594; called by muse, mutect2, varscan2
- PRR33 | c.600C>T p.A200= | Silent (SNP) | VAF 404/597 reads (68%) | called by muse, mutect2, varscan2
- PTCH1 | c.4086C>T p.P1362= | Silent (SNP) | VAF 294/475 reads (62%) | catalogued as rs375588552; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN2A | c.4299T>C p.D1433= | Silent (SNP) | VAF 56/228 reads (25%) | catalogued as rs1384577551; called by muse, mutect2, varscan2
- TBX3 | c.1944G>T p.P648= (on ENST00000257566 / NM_016569.4; = p.P628= on NM_005996.4) | Silent (SNP) | VAF 186/561 reads (33%) | catalogued as rs764442602; called by muse, mutect2, varscan2
- TRPC3 | c.948C>T p.N316= (on ENST00000379645 / NM_001366479.2; = p.N243= on NM_003305.2) | Silent (SNP) | VAF 166/328 reads (51%) | catalogued as COSV53376987; called by muse, mutect2, varscan2
- TTC29 | c.270G>A p.R90= | Silent (SNP) | VAF 135/520 reads (26%) | called by muse, mutect2, varscan2
- YJEFN3 | c.195G>A p.G65= | Silent (SNP) | VAF 78/169 reads (46%) | called by muse, mutect2, varscan2
- ZBTB7A | c.1173C>T p.I391= | Silent (SNP) | VAF 156/333 reads (47%) | called by muse, mutect2, varscan2
- ZSWIM1 | c.663C>T p.I221= | Silent (SNP) | VAF 256/490 reads (52%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.30C>T p.P10= | Silent (SNP) | VAF 100/216 reads (46%) | catalogued as rs1327383524; called by muse, varscan2
- ATP6AP1L | n.1327del | RNA (DEL) | VAF 78/359 reads (22%) | called by mutect2, pindel, varscan2
- KIF1A | c.2555+871C>T | Intron (SNP) | VAF 312/678 reads (46%) | catalogued as rs1553632633; ClinVar: uncertain significance; called by muse, varscan2
- SH2D3A | c.*1G>A | 3'UTR (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- SSX3 | c.466+43G>C | Intron (SNP) | VAF 251/251 reads (100%) | catalogued as rs782376900; called by muse, mutect2, varscan2
